Somatic mutation profile of tumor specimen TCGA-21-5786-01A (aliquot TCGA-21-5786-01A-01D-1632-08) from TCGA case TCGA-21-5786, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.7 years (23,649 days).
Specimen TCGA-21-5786-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 727179ad-fa54-432c-87d5-270b360ca5f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-5786-10A (Blood Derived Normal), aliquot TCGA-21-5786-10A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7ed2f87-298a-40fd-b8f7-0161cdb94eb0

The open-access MAF lists 419 somatic variants for this specimen: 325 protein-altering or splice-affecting, 82 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 283, Silent 82, Nonsense Mutation 22, Frame Shift Del 12, Splice Site 6, RNA 4, 3'Flank 3, 5'Flank 2, Intron 2, 5'UTR 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3546C>A p.N1182K | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.209); catalogued as COSV55294316; called by muse, mutect2, varscan2
- AARS2 | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55116277; called by muse, mutect2, varscan2
- ABCC12 | c.3943C>A p.L1315I | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0.37); catalogued as COSV60915673; called by muse, varscan2
- ACKR3 | c.615C>G p.I205M | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV56022580; called by muse, mutect2
- ACTG2 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61828907; called by muse, mutect2, varscan2
- ACTN2 | c.2667C>A p.Y889* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100856441, COSV63976601; called by muse, mutect2, varscan2
- ADAMTS12 | c.3805C>A p.L1269M | Missense Mutation (SNP) | VAF 53/270 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.191); catalogued as COSV61269242; called by muse, mutect2, varscan2
- ADAMTS12 | c.3804C>A p.H1268Q | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61269253; called by muse, mutect2, varscan2
- ADAMTS18 | c.2764G>C p.E922Q | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV51418879; called by muse, mutect2, varscan2
- ADAMTS20 | c.3647G>T p.W1216L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV67134761; called by muse, mutect2
- ADAMTS20 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67134770; called by muse, mutect2, varscan2
- ADCYAP1 | c.15C>A p.S5R | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs748744145, COSV52486970; called by muse, mutect2, varscan2
- ADGRB3 | c.2720G>C p.R907P | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV53252143; called by muse, mutect2, varscan2
- AGL | c.2612G>T p.S871I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV54055281; called by muse, mutect2
- AGO2 | c.216-2A>T p.X72_splice | Splice Site (SNP) | VAF 26/86 reads (30%) | catalogued as COSV55049534; called by muse, mutect2, varscan2
- AKAP3 | c.1824G>T p.K608N | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.836); catalogued as COSV57418241; called by muse, mutect2
- ALMS1 | c.7868G>C p.R2623T | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV52514607, COSV52520324; called by muse, mutect2, varscan2
- AMHR2 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV57686291; called by muse, mutect2
- ANK2 | c.5407C>A p.H1803N | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.07); catalogued as COSV52173048; called by muse, mutect2, varscan2
- ANO2 | c.2144C>G p.T715S (on ENST00000356134 / NM_001278597.3; = p.T719S on NM_001278596.3) | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV59031962; called by muse, mutect2, varscan2
- AP002512.3 | c.1169C>A p.P390H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54406416, COSV54407710; called by muse, mutect2, varscan2
- AP002512.3 | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.03); catalogued as COSV54407719; called by muse, mutect2, varscan2
- AQP8 | c.322G>C p.V108L | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54846351, COSV54846402; called by muse, mutect2, varscan2
- ARHGAP18 | c.1091T>G p.L364* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV63765207; called by muse, mutect2, varscan2
- ARSG | c.172A>C p.T58P | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV71593584; called by muse, mutect2, varscan2
- ASB17 | c.540C>A p.N180K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.968); catalogued as COSV52411129; called by muse, mutect2, varscan2
- ATP1A4 | c.2929A>T p.T977S | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV63627213, COSV63628966; called by muse, mutect2, varscan2
- ATP2A2 | c.2278A>C p.I760L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV57875776; called by muse, varscan2
- AVPR2 | c.751C>A p.R251S | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as COSV61686534; called by muse, mutect2, varscan2
- BRINP3 | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748757778, COSV66531106; called by muse, mutect2, varscan2
- BRSK1 | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58668058; called by muse, mutect2, varscan2
- C12orf50 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs189840625, COSV53893594; called by muse, mutect2, varscan2
- CACNA1I | c.5956C>T p.P1986S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV60813245; called by muse, mutect2
- CBLL1 | c.465T>G p.I155M | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV56029698; called by muse, mutect2, varscan2
- CCDC102A | c.1277G>A p.G426D | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as COSV50775933; called by muse, mutect2, varscan2
- CCDC137 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); catalogued as COSV61303570; called by muse, mutect2, varscan2
- CCDC51 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV67478761; called by muse, mutect2, varscan2
- CCDC54 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV53759195, COSV53759745; called by muse, mutect2, varscan2
- CCER1 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as rs746803573, COSV62647640; called by muse, mutect2, varscan2
- CCNK | c.395T>A p.F132Y | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.636); catalogued as COSV66275272; called by muse, mutect2, varscan2
- CCR8 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 81/162 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58337576; called by muse, mutect2, varscan2
- CCT8L2 | c.254C>A p.P85Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63463101; called by muse, mutect2, varscan2
- CD93 | c.1783C>A p.L595I | Missense Mutation (SNP) | VAF 49/315 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV55666782; called by muse, mutect2, varscan2
- CDH12 | c.2231G>A p.S744N | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66423038; called by muse, mutect2
- CDH8 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV54881279; called by muse, mutect2, varscan2
- CDHR3 | c.345C>A p.D115E | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58419120; called by muse, mutect2, varscan2
- CDKN2A | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58704563; called by muse, mutect2, varscan2
- CEP350 | c.6609G>T p.Q2203H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.38); catalogued as COSV62605797; called by muse, mutect2
- CES1 | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV62088408; called by muse, mutect2, varscan2
- CHEK2 | c.1224+2T>C p.X408_splice (on ENST00000382580 / NM_001005735.2; = p.X365_splice on NM_007194.4) | Splice Site (SNP) | VAF 18/36 reads (50%) | catalogued as COSV60422675; called by muse, mutect2, varscan2
- CKM | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 50/141 reads (35%) | catalogued as COSV55533147, COSV55534105; called by muse, mutect2, varscan2
- CNN1 | c.371T>A p.L124H | Missense Mutation (SNP) | VAF 49/85 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52956469; called by muse, mutect2, varscan2
- CNNM1 | c.1423A>G p.I475V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV63202642; called by muse, mutect2, varscan2
- CNOT1 | c.3163A>T p.T1055S | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55319335; called by muse, mutect2, varscan2
- CNPY1 | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV58787794; called by muse, mutect2, varscan2
- COL11A1 | c.1033G>T p.G345* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as COSV62175198, COSV62189181; called by muse, mutect2, varscan2
- COL25A1 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67653568; called by muse, mutect2, varscan2
- CREM | c.949C>T p.R317* (on ENST00000429130; = p.R272* on NM_181571.3) | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as COSV59768599; called by muse, mutect2
- CRISP2 | c.611G>T p.S204I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs772587233, COSV59255599; called by muse, mutect2, varscan2
- CSMD1 | c.3612A>T p.Q1204H (on ENST00000520002; = p.Q1203H on NM_033225.6) | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV59347704; called by muse, mutect2, varscan2
- CSMD3 | c.5601C>A p.Y1867* (on ENST00000297405 / NM_001363185.1; = p.Y1763* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV52124260; called by mutect2, varscan2
- CSMD3 | c.780G>T p.E260D | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV52239328; called by muse, mutect2, varscan2
- CSRNP3 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV58781719; called by muse, mutect2, varscan2
- CTDP1 | c.2360G>T p.R787L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.04); catalogued as COSV50005802; called by muse, mutect2, varscan2
- CTR9 | c.1402G>T p.G468W | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV63729064; called by muse, mutect2, varscan2
- CUTC | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs758959570, COSV65081973; called by muse, mutect2, varscan2
- CXorf66 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 146/203 reads (72%) | catalogued as COSV65169481; called by muse, mutect2, varscan2
- DACT1 | c.1817G>T p.R606L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100242081, COSV60021932; called by muse, mutect2, varscan2
- DCAF4L1 | c.720T>A p.F240L | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV60787858; called by muse, mutect2, varscan2
- DCC | c.3824C>A p.P1275Q | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.928); catalogued as COSV71429898; called by muse, mutect2, varscan2
- DCDC1 | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV60836779, COSV60849362; called by muse, mutect2, varscan2
- DEPTOR | c.224A>T p.E75V | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV53818359; called by muse, mutect2, varscan2
- DHX16 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as COSV64564691; called by muse, mutect2, varscan2
- DLGAP1 | c.2384G>C p.W795S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59818065; called by muse, mutect2, varscan2
- DMRTC2 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV54187372; called by muse, mutect2, varscan2
- DNAH8 | c.6409G>T p.V2137F | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59437850, COSV59462245; called by muse, mutect2, varscan2
- DOCK6 | c.3994C>T p.R1332* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as rs776952607, COSV53917852, COSV53920674; called by muse, mutect2, varscan2
- DRP2 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65810987; called by muse, mutect2, varscan2
- DSG1 | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV57137186; called by muse, mutect2, varscan2
- DYSF | c.2297C>A p.P766H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.195); catalogued as COSV99245928; called by muse, mutect2, varscan2
- DYSF | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50470793, COSV99249582; called by muse, mutect2, varscan2
- ENDOU | c.776T>C p.F259S (on ENST00000422538 / NM_001172439.2; = p.F218S on NM_006025.4) | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57465458; called by muse, mutect2, varscan2
- ENPP3 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.483); catalogued as COSV62955203; called by muse, mutect2, varscan2
- EPB41L5 | c.878A>T p.K293I | Missense Mutation (SNP) | VAF 263/331 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55354499; called by muse, mutect2, varscan2
- EPHA3 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV60714781, COSV60715407; called by muse, mutect2, varscan2
- ERICH6 | c.991C>A p.H331N | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV99901536; called by muse, mutect2, varscan2
- ESRRG | c.518C>A p.T173K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63169424; called by muse, mutect2, varscan2
- EXOC3L1 | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52047366; called by muse, mutect2, varscan2
- FAM110B | c.528G>C p.E176D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV64066489; called by muse, mutect2, varscan2
- FAM167A | c.18C>G p.I6M | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.035); catalogued as rs1462005505, COSV52704366; called by muse, mutect2, varscan2
- FAM47A | c.2236A>T p.K746* | Nonsense Mutation (SNP) | VAF 66/88 reads (75%) | catalogued as COSV60498230; called by muse, mutect2, varscan2
- FANCA | c.3224T>C p.L1075P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs766559253, COSV59797406; called by muse, mutect2
- FAT1 | c.9179A>G p.Y3060C | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71675003; called by muse, mutect2, varscan2
- FBN3 | c.8356G>C p.G2786R | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV53664559; called by muse, mutect2, varscan2
- FCRLB | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs752827894, COSV61060185; called by muse, mutect2, varscan2
- FMN2 | c.2192A>G p.K731R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV60439582; called by muse, mutect2, varscan2
- FOXD4L1 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 393/555 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484664140, COSV99380437, COSV99380905; called by muse, mutect2, varscan2
- FRRS1L | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV73746722; called by muse, mutect2, varscan2
- FRY | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66573794; called by muse, mutect2, varscan2
- FSHR | c.2080C>A p.Q694K | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV100436904; called by muse, mutect2
- GBA3 | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72438366; called by muse, mutect2, varscan2
- GBA3 | c.614G>A p.W205* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as rs971016595, COSV72438367; called by muse, mutect2, varscan2
- GBA3 | c.973G>C p.G325R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV72438368; called by muse, mutect2
- GBE1 | c.1121C>T p.S374L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs776192396, COSV70099031, COSV70100899; called by muse, mutect2
- GHR | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as COSV50119402; called by muse, mutect2, varscan2
- GOLGB1 | c.4408G>T p.E1470* | Nonsense Mutation (SNP) | VAF 92/261 reads (35%) | catalogued as COSV61467864; called by muse, mutect2, varscan2
- GTF2B | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65137179, COSV65137355; called by muse, mutect2, varscan2
- HAUS6 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs539387980, COSV100997863, COSV65839513; called by muse, varscan2
- HCN1 | c.1771C>A p.L591I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV57522694; called by muse, mutect2, varscan2
- HIVEP3 | c.5640G>T p.E1880D | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV56018624; called by muse, mutect2, varscan2
- HK2 | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51873638, COSV51877065, COSV99309713; called by muse, mutect2
- IGSF9B | c.2862del p.P956Lfs*37 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as COSV100318266; called by mutect2, pindel
- IL12RB2 | c.2122A>G p.S708G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV52024855; called by muse, mutect2, varscan2
- IL9R | c.1135C>G p.P379A | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.092); catalogued as rs747029804, COSV54900860; called by muse, mutect2, varscan2
- INTS6 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60879306; called by muse, mutect2, varscan2
- IPO9 | c.1110C>G p.I370M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.542); catalogued as COSV64234448; called by muse, mutect2, varscan2
- ITFG2 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV57390192; called by muse, mutect2, varscan2
- KCNB2 | c.1814G>T p.S605I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV73051280; called by muse, mutect2, varscan2
- KCNG4 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs199803012; called by muse, mutect2, varscan2
- KDR | c.1860C>A p.S620R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.46); catalogued as COSV55769876; called by muse, mutect2, varscan2
- KDR | c.140C>A p.T47K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV55769889; called by muse, mutect2, varscan2
- KIAA1755 | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1338894160, COSV54078325; called by muse, mutect2, varscan2
- KLHL31 | c.1264T>A p.Y422N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63882066; called by muse, mutect2
- KLHL42 | c.1372G>T p.V458F | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as COSV67145694; called by muse, mutect2, varscan2
- KLK15 | c.743G>A p.W248* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV56827572; called by muse, mutect2, varscan2
- KMT2C | c.10558C>T p.P3520S | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51464305; called by muse, mutect2
- KPNA4 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV62076329; called by muse, mutect2
- LINGO2 | c.1121A>T p.Q374L | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58061627; called by muse, mutect2, varscan2
- LPA | c.4736G>A p.C1579Y | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60305238; called by muse, mutect2, varscan2
- LRRC28 | c.149G>T p.R50M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1052658462, COSV57339688; called by muse, mutect2, varscan2
- LRRK2 | c.5050C>G p.H1684D | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.344); catalogued as COSV100109792; called by muse, mutect2, varscan2
- MAGEB18 | c.859T>A p.F287I | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57464542; called by muse, mutect2, varscan2
- MANSC1 | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67111215; called by muse, mutect2, varscan2
- MAST4 | c.6836G>A p.R2279K (on ENST00000403625 / NM_001164664.2; = p.R2090K on NM_015183.3) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV55132114; called by muse, mutect2, varscan2
- MAST4 | c.6837G>T p.R2279S (on ENST00000403625 / NM_001164664.2; = p.R2090S on NM_015183.3) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as COSV55132146; called by muse, mutect2, varscan2
- MBL2 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV64758923; called by muse, mutect2, varscan2
- MCM5 | c.1111C>A p.R371S | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs199576845, COSV53347155; called by muse, mutect2, varscan2
- MDGA2 | c.1546C>A p.P516T (on ENST00000399232 / NM_001113498.2; = p.P218T on NM_182830.4) | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV62093195; called by muse, mutect2, varscan2
- MED25 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV57205859; called by muse, mutect2, varscan2
- MEI1 | c.2180A>T p.D727V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55900236, COSV55904781; called by muse, mutect2, varscan2
- MON2 | c.3112C>A p.P1038T | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54810239; called by muse, mutect2, varscan2
- MS4A4A | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as COSV59702155; called by muse, mutect2
- MYH3 | c.251A>T p.K84M | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV56867139; called by muse, mutect2, varscan2
- MYL1 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV58976014; called by muse, mutect2
- MYL3 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV52767948; called by muse, mutect2, varscan2
- MYO16 | c.1136G>T p.S379I | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV51804538; called by muse, mutect2, varscan2
- MYO18B | c.4093G>A p.A1365T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59140648; called by muse, mutect2, varscan2
- NALCN | c.1091T>A p.V364E | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV51948595; called by muse, mutect2, varscan2
- NAMPT | c.1262C>G p.P421R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.627); catalogued as COSV55995745; called by muse, mutect2, varscan2
- NCAPG2 | c.2824G>T p.D942Y | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV51989430; called by muse, mutect2
- NCKAP1L | c.2306C>T p.A769V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1360943321, COSV53209283; called by muse, mutect2, varscan2
- NEK5 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV62880936; called by muse, mutect2, varscan2
- NELL1 | c.56-1G>A p.X19_splice | Splice Site (SNP) | VAF 30/50 reads (60%) | catalogued as COSV54289578; called by muse, mutect2, varscan2
- NEO1 | c.198A>T p.R66S | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs200575571, COSV56074478; called by muse, mutect2, varscan2
- NEO1 | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1037063342, COSV56074491; called by muse, mutect2
- NFATC2 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.643); catalogued as rs753968378, COSV65354447; called by muse, mutect2, varscan2
- NPAP1 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV61508795, COSV61512830; called by muse, mutect2
- NPR3 | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV54087429, COSV54090021; called by muse, mutect2, varscan2
- NR5A2 | c.979C>A p.Q327K (on ENST00000367362 / NM_205860.3; = p.Q281K on NM_003822.5) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV52653498; called by muse, mutect2, varscan2
- NRXN3 | c.2986G>T p.G996C (on ENST00000335750 / NM_001330195.2; = p.G623C on NM_004796.6) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59765071; called by muse, mutect2, varscan2
- NUTM2A | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.009); catalogued as COSV101095788, COSV67742017; called by muse, mutect2, varscan2
- OBSCN | c.3701G>C p.G1234A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV52795816; called by muse, mutect2, varscan2
- OCA2 | c.2245-1G>T p.X749_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as rs1344047706, COSV62351143; called by muse, mutect2, varscan2
- OPCML | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as COSV59435220; called by muse, mutect2, varscan2
- OPLAH | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782155304, COSV70678614; called by muse, mutect2
- OPTC | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV65868149; called by muse, mutect2, varscan2
- OR10Z1 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV63524741; called by muse, mutect2, varscan2
- OR2AK2 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.022); catalogued as COSV63555913; called by muse, mutect2, varscan2
- OR2T10 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100393745, COSV57897393; called by muse, mutect2, varscan2
- OR2T12 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 47/77 reads (61%) | catalogued as rs758097699, COSV58778427; called by muse, mutect2, varscan2
- OR2T6 | c.101T>C p.V34A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1457124518, COSV63216707; called by muse, mutect2, varscan2
- OR4D5 | c.500C>A p.P167Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58308214; called by muse, mutect2, varscan2
- OR4F6 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs769055061, COSV61027123; called by muse, mutect2, varscan2
- OR5D16 | c.328G>C p.V110L | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV101004024, COSV65722399; called by muse, mutect2, varscan2
- OR5F1 | c.371C>A p.A124E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs780899733, COSV53547432, COSV99558435; called by muse, mutect2, varscan2
- OR5I1 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs777031683, COSV56888051; called by muse, mutect2, varscan2
- OR5M1 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV73202258; called by muse, mutect2, varscan2
- OR5T1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57303690; called by muse, mutect2, varscan2
- OR5T1 | c.722A>C p.Q241P | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV57303701; called by muse, mutect2, varscan2
- OR5T1 | c.723G>T p.Q241H | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778624045, COSV57303716, COSV57304542; called by muse, mutect2, varscan2
- OR6N1 | c.396C>A p.Y132* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV58649442; called by muse, mutect2, varscan2
- OR9I1 | c.537T>G p.C179W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100109955, COSV56926948; called by muse, mutect2, varscan2
- OSR2 | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as COSV52557892, COSV52558339; called by muse, mutect2, varscan2
- PARP8 | c.2170G>T p.G724C | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55862889; called by muse, mutect2, varscan2
- PCDH10 | c.2672G>C p.R891T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.272); catalogued as COSV52098635; called by muse, mutect2, varscan2
- PCDH11X | c.2800G>T p.D934Y | Missense Mutation (SNP) | VAF 78/94 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53483887; called by muse, mutect2, varscan2
- PCDH15 | c.5111G>T p.R1704M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as COSV57347742; called by muse, mutect2, varscan2
- PCDHB10 | c.699G>T p.L233F | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV53381266; called by muse, mutect2, varscan2
- PCDHGA1 | c.1976C>T p.T659M | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1291170199, COSV65297729; called by muse, mutect2, varscan2
- PCNX1 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs538674473, COSV53091715; called by muse, mutect2, varscan2
- PDGFRA | c.2508C>G p.D836E | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57270659; called by muse, mutect2, varscan2
- PHLDB3 | c.187A>G p.S63G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV52670602; called by muse, mutect2, varscan2
- PIK3R4 | c.29C>G p.P10R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100768546, COSV63242192; called by muse, mutect2, varscan2
- PIRT | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.272); catalogued as COSV74119916; called by muse, mutect2, varscan2
- PIWIL2 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV63252595; called by muse, mutect2
- PLEKHG4 | c.3533G>C p.G1178A | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV58573753; called by muse, mutect2, varscan2
- PNPLA1 | c.457T>A p.F153I (on ENST00000394571 / NM_001374623.1; = p.F58I on NM_173676.2) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57235851; called by muse, mutect2, varscan2
- PPM1A | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57787652; called by muse, mutect2, varscan2
- PPP3CB | c.562A>G p.M188V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV61153389; called by muse, mutect2, varscan2
- PRDM2 | c.4584G>T p.Q1528H | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.188); catalogued as COSV52450528; called by muse, mutect2, varscan2
- PRKDC | c.10585A>G p.I3529V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs1000338239, COSV58057573; called by muse, mutect2, varscan2
- PTCH1 | c.3424G>A p.G1142R | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1339085767, COSV59483405; called by muse, mutect2, varscan2
- PTPRK | c.1831A>T p.T611S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV63902428; called by muse, mutect2, varscan2
- PYGB | c.1004C>A p.A335D | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53820408; called by muse, mutect2, varscan2
- RAB2A | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV52911701, COSV52912721; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761783875, COSV51484865; called by muse, mutect2, varscan2
- RBM47 | c.995G>T p.R332M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV55938293; called by muse, mutect2, varscan2
- RCOR3 | c.152A>T p.K51M | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65366207; called by muse, mutect2, varscan2
- RCVRN | c.251A>G p.K84R | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.89); PolyPhen benign (0.075); catalogued as COSV56841898; called by muse, mutect2, varscan2
- REG1A | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52070422; called by muse, varscan2
- REG3A | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59410478; called by muse, mutect2, varscan2
- RELN | c.532T>A p.C178S | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV59016663; called by muse, mutect2, varscan2
- RERGL | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as COSV57462505; called by muse, mutect2, varscan2
- RERGL | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV57462518; called by muse, mutect2, varscan2
- RFPL2 | c.1039T>A p.S347T | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.288); catalogued as COSV50713296; called by muse, mutect2, varscan2
- RGS12 | c.217A>T p.K73* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV60907399; called by muse, mutect2, varscan2
- RNF133 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT tolerated (0.45); PolyPhen benign (0.063); catalogued as rs267601255, COSV57372987; called by muse, mutect2, varscan2
- RPS6KA5 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56223434; called by muse, mutect2, varscan2
- RYR2 | c.1525A>T p.S509C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV63697535, COSV63710568; called by muse, mutect2, varscan2
- SAGE1 | c.2150C>A p.A717D | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61015167; called by muse, mutect2, varscan2
- SALL1 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1485810289, COSV51760744; called by muse, mutect2, varscan2
- SALL3 | c.1223A>T p.E408V | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV73306224; called by muse, mutect2, varscan2
- SARAF | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56357822; called by muse, mutect2, varscan2
- SAXO2 | c.1183G>T p.V395L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59754536; called by muse, mutect2, varscan2
- SCARF2 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as rs1250640695, COSV56733128; called by muse, mutect2, varscan2
- SDCCAG8 | c.440A>T p.K147I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59412710; called by muse, mutect2, varscan2
- SDE2 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs979841467, COSV55251965; called by muse, mutect2, varscan2
- SEC24B | c.2226G>T p.L742F | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV54502566; called by muse, mutect2, varscan2
- SEC63 | c.802C>G p.P268A | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.625); catalogued as COSV64600924; called by muse, mutect2, varscan2
- SEMA3E | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57098184; called by muse, mutect2, varscan2
- SERPINA12 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as rs1282825407, COSV57944743; called by muse, mutect2, varscan2
- SESN3 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.068); catalogued as COSV53586034; called by muse, mutect2, varscan2
- SEZ6L | c.2951A>T p.Y984F | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.676); catalogued as COSV50670528; called by muse, mutect2
- SFMBT2 | c.1630A>G p.N544D | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62812652; called by muse, mutect2, varscan2
- SGMS1 | c.380A>T p.Q127L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.119); catalogued as COSV62369774, COSV62371261; called by muse, mutect2, varscan2
- SHANK1 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs754465479, COSV53255786; called by muse, mutect2
- SHPRH | c.3127G>A p.A1043T (on ENST00000275233 / NM_001042683.3; = p.A1052T on NM_173082.3) | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51613239; called by muse, mutect2, varscan2
- SIK3 | c.3938G>T p.C1313F (on ENST00000445177 / NM_001366686.2; = p.C1271F on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); catalogued as COSV52618398; called by muse, mutect2, varscan2
- SIPA1L2 | c.2624G>T p.G875V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV53394247; called by muse, mutect2, varscan2
- SLC25A28 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65125542; called by muse, mutect2, varscan2
- SLC25A6 | c.888G>C p.K296N | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV58432338; called by muse, mutect2, varscan2
- SLC7A3 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV53228206; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2209G>A p.D737N (on ENST00000540229 / NM_001371097.1; = p.D676N on NM_001009562.4) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs951327157, COSV67446610; called by muse, mutect2, varscan2
- SLCO5A1 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV52662982; called by muse, mutect2, varscan2
- SLIT2 | c.3349A>C p.M1117L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV56581807; called by muse, mutect2
- SLIT3 | c.2230C>A p.R744S | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV60609781, COSV60620013; called by muse, mutect2, varscan2
- SLITRK3 | c.1901G>C p.G634A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV53850361; called by muse, mutect2, varscan2
- SLITRK3 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV53850373; called by muse, mutect2, varscan2
- SMARCA4 | c.1562G>C p.R521P | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60801413, COSV60812674; called by muse, mutect2, varscan2
- SMC3 | c.2192C>G p.S731C | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as COSV62421093; called by muse, mutect2, varscan2
- SORCS1 | c.3371G>T p.R1124M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV53884307; called by muse, mutect2, varscan2
- SORCS3 | c.865C>A p.Q289K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV63816452, COSV63817022; called by muse, mutect2, varscan2
- SPATA7 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV50418570; called by muse, mutect2, varscan2
- SPHKAP | c.3197G>T p.R1066L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100763991, COSV60889811; called by muse, mutect2, varscan2
- SSTR4 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 88/145 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV54798962; called by muse, mutect2, varscan2
- SSX2IP | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV60553585; called by muse, mutect2, varscan2
- ST14 | c.2527C>G p.P843A | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV53834652; called by muse, mutect2, varscan2
- STK4 | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV65670887; called by muse, mutect2, varscan2
- SYN3 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60501987, COSV60511593; called by muse, mutect2, varscan2
- SYNDIG1 | c.480G>A p.E160= | Splice Region (SNP) | VAF 31/160 reads (19%) | catalogued as COSV65237247; called by muse, mutect2, varscan2
- SYNE1 | c.7186T>C p.C2396R (on ENST00000367255 / NM_182961.4; = p.C2403R on NM_033071.3) | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV55032008; called by muse, mutect2
- SYNE1 | c.7098G>T p.L2366F (on ENST00000367255 / NM_182961.4; = p.L2373F on NM_033071.3) | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55032050; called by muse, mutect2, varscan2
- SYT1 | c.80C>G p.T27R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV54059155; called by muse, mutect2, varscan2
- TBL1Y | c.634A>T p.S212C | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as rs761201938, COSV60733411; called by muse, mutect2, varscan2
- TDRD6 | c.2588A>G p.K863R | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as COSV60176848; called by muse, mutect2, varscan2
- TGIF2LX | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV52214530; called by muse, mutect2, varscan2
- TIAM1 | c.3761G>T p.G1254V | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as rs767264861, COSV54561235; called by muse, mutect2, varscan2
- TINAG | c.1015C>G p.P339A | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52510954, COSV52512085; called by muse, mutect2, varscan2
- TMEM125 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs748336796, COSV71326954; called by muse, mutect2, varscan2
- TMEM132B | c.2821C>T p.H941Y | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54759811; called by muse, mutect2, varscan2
- TMEM40 | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53147077; called by muse, mutect2, varscan2
- TMPRSS9 | c.1415C>A p.A472D (on ENST00000648592; = p.A438D on NM_182973.2) | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); catalogued as COSV60229291; called by muse, mutect2, varscan2
- TNFRSF11A | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs1312726610, COSV54024737; called by muse, mutect2, varscan2
- TNRC6B | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.573); catalogued as COSV57300988; called by muse, mutect2, varscan2
- TPTE2 | c.719C>G p.S240C (on ENST00000400230 / NM_199254.2; = p.S163C on NM_130785.3) | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55020919, COSV55024531, COSV55024595; called by muse, mutect2, varscan2
- TRAPPC10 | c.1156G>T p.V386L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as rs775279067, COSV52379170; called by muse, mutect2, varscan2
- TRIM9 | c.1989C>A p.N663K | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53613019, COSV53620580; called by muse, mutect2
- TRPM7 | c.2955G>T p.Q985H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1407999784, COSV57919035; called by muse, mutect2, varscan2
- TXLNB | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV64444765; called by muse, mutect2, varscan2
- UBE2E3 | c.581A>G p.H194R | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66585578; called by muse, mutect2, varscan2
- UBQLN3 | c.1145del p.P382Hfs*20 | Frame Shift Del (DEL) | VAF 45/99 reads (45%) | catalogued as COSV61165269; called by mutect2, pindel, varscan2
- UBR7 | c.345+1G>C p.X115_splice | Splice Site (SNP) | VAF 8/15 reads (53%) | catalogued as COSV50150341; called by muse, mutect2, varscan2
- UGT2B4 | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV59318548; called by muse, mutect2, varscan2
- UNC13C | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as COSV52896346; called by muse, mutect2, varscan2
- URB2 | c.818A>T p.N273I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV51003986; called by muse, mutect2, varscan2
- VCPIP1 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as COSV60048961; called by muse, mutect2, varscan2
- VEPH1 | c.1786G>T p.G596C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs747252298, COSV62880638; called by muse, mutect2, varscan2
- VWF | c.7288-1G>A p.X2430_splice | Splice Site (SNP) | VAF 45/114 reads (39%) | catalogued as COSV54626521; called by muse, mutect2, varscan2
- WDR62 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53078560; called by muse, mutect2, varscan2
- WNT5B | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV60198451; called by muse, mutect2, varscan2
- XIRP2 | c.7369A>T p.T2457S (on ENST00000628543; = p.T2632S on NM_152381.6) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV54715014; called by muse, mutect2, varscan2
- XKR4 | c.791T>A p.L264H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59326545; called by muse, mutect2, varscan2
- ZBTB18 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62397809; called by muse, mutect2, varscan2
- ZDBF2 | c.2316A>T p.K772N | Missense Mutation (SNP) | VAF 62/107 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV65627834; called by muse, mutect2, varscan2
- ZDBF2 | c.7048G>T p.G2350C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.667); catalogued as COSV65627838; called by muse, mutect2, varscan2
- ZFC3H1 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV57349270; called by muse, mutect2, varscan2
- ZNF333 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 36/67 reads (54%) | catalogued as COSV52887209; called by muse, mutect2, varscan2
- ZNF33A | c.378T>A p.N126K (on ENST00000458705 / NM_006974.3; = p.N127K on NM_006954.2) | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV56726412; called by muse, mutect2, varscan2
- ZNF492 | c.648G>C p.K216N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1213022506, COSV101513981; called by mutect2, varscan2
- ZNF519 | c.828G>T p.R276S | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs970915816, COSV73913482; called by muse, mutect2, varscan2
- ZNF555 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as rs190919658, COSV62072915, COSV62073485; called by muse, mutect2, varscan2
- ZSCAN22 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 93/243 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61639364; called by muse, mutect2, varscan2
- ZSCAN25 | c.1140T>G p.C380W | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53553770; called by muse, mutect2, varscan2
- AHNAK2 | c.15425del p.P5142Qfs*2 | Frame Shift Del (DEL) | VAF 15/108 reads (14%) | called by mutect2, pindel, varscan2
- ARHGEF35 | c.564G>T p.E188D | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.254); called by mutect2, varscan2
- C2CD2L | c.694_703del p.Q232Sfs*7 | Frame Shift Del (DEL) | VAF 27/109 reads (25%) | called by mutect2, pindel, varscan2
- ERICH3 | c.1123_1129del p.R375Efs*48 | Frame Shift Del (DEL) | VAF 16/28 reads (57%) | called by mutect2, pindel, varscan2
- HECW1 | c.1135del p.E379Nfs*32 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.342C>A p.Y114* | Nonsense Mutation (SNP) | VAF 281/544 reads (52%) | called by muse, mutect2, varscan2
- IGHV2-26 | c.119C>A p.T40N | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV1-27 | c.77T>G p.M26R | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- IGLV6-57 | c.320_329del p.D107Vfs*? | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by pindel, varscan2*
- MRC1 | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.958); called by muse, mutect2
- OR4M1 | c.216del p.W72Cfs*12 | Frame Shift Del (DEL) | VAF 101/207 reads (49%) | called by mutect2, pindel, varscan2
- OTOGL | c.5866_5869del p.I1956Lfs*19 (on ENST00000547103; = p.I1947Lfs*19 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by pindel, varscan2
- PRAMEF15 | c.1121C>A p.P374H | Missense Mutation (SNP) | VAF 90/156 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PRAMEF18 | c.112_113del p.P38Tfs*8 | Frame Shift Del (DEL) | VAF 31/190 reads (16%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.806T>A p.L269H | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRX | c.2287_2298del p.V763_V766del | In Frame Del (DEL) | VAF 47/167 reads (28%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.2760G>T p.K920N (on ENST00000621492; = p.K886N on NM_025248.3) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRBV30 | c.100A>G p.S34G | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRHDE | c.1905del p.N635Kfs*9 | Frame Shift Del (DEL) | VAF 38/114 reads (33%) | called by mutect2, pindel, varscan2
- ZNF519 | c.108_109del p.N36Kfs*41 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- ABCC12 | c.3942C>A p.R1314= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV60915677; called by muse, varscan2
- ACTG2 | c.396C>T p.A132= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as COSV61828897; called by muse, mutect2, varscan2
- ADGRG4 | c.2256T>A p.P752= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as COSV54961285; called by muse, mutect2, varscan2
- API5 | c.549A>T p.L183= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV66634001; called by muse, mutect2, varscan2
- ASIC2 | c.468C>T p.F156= | Silent (SNP) | VAF 46/76 reads (61%) | catalogued as rs1046043534, COSV63316609; called by muse, mutect2, varscan2
- CACNA1E | c.987G>A p.L329= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV62404848; called by muse, mutect2, varscan2
- CASP2 | c.327C>T p.T109= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV60082799; called by muse, mutect2, varscan2
- CBL | c.261G>A p.L87= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV50646297; called by muse, mutect2, varscan2
- CBL | c.1401C>A p.L467= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs994318998, COSV50646331; called by muse, mutect2
- CD96 | c.747T>A p.I249= (on ENST00000283285 / NM_198196.3; = p.I233= on NM_005816.5) | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV51919064; called by muse, mutect2, varscan2
- CDH18 | c.1437G>T p.L479= | Silent (SNP) | VAF 41/161 reads (25%) | catalogued as COSV56939132; called by muse, mutect2, varscan2
- CFAP100 | c.1000C>A p.R334= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV61502548, COSV61503687; called by muse, mutect2, varscan2
- CRACD | c.99G>T p.L33= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99948994; called by muse, mutect2, varscan2
- CREM | c.951A>C p.R317= (on ENST00000429130; = p.R272= on NM_181571.3) | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV59768612; called by muse, mutect2
- CTTNBP2 | c.384G>A p.Q128= | Silent (SNP) | VAF 13/207 reads (6%) | catalogued as COSV50420295; called by muse, mutect2
- CXCR3 | c.429C>G p.A143= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV65462125; called by muse, mutect2, varscan2
- CYP2W1 | c.687G>A p.L229= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as COSV58270810; called by muse, mutect2, varscan2
- DNAJC13 | c.1821A>G p.E607= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs1220272788, COSV53453979; called by muse, mutect2, varscan2
- DPF3 | c.87A>C p.S29= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV63501239; called by muse, mutect2, varscan2
- EIF3A | c.3201G>T p.R1067= | Silent (SNP) | VAF 70/224 reads (31%) | catalogued as rs371721985, COSV64962062; called by muse, varscan2
- ENOSF1 | c.318G>T p.L106= (on ENST00000340116 / NM_001354066.2; = p.L58= on NM_017512.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as COSV51893886; called by muse, mutect2, varscan2
- EXT1 | c.636C>T p.G212= | Silent (SNP) | VAF 70/143 reads (49%) | catalogued as COSV100983545, COSV65482006; called by muse, mutect2, varscan2
- GALT | c.483G>T p.L161= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV66593209; called by muse, mutect2, varscan2
- GDPD3 | c.378C>T p.H126= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs370168697; called by muse, mutect2, varscan2
- GPCPD1 | c.1005G>A p.L335= | Silent (SNP) | VAF 51/95 reads (54%) | catalogued as COSV66831257; called by muse, mutect2, varscan2
- GRIN2B | c.1596A>T p.T532= | Silent (SNP) | VAF 76/171 reads (44%) | catalogued as COSV74206736; called by muse, mutect2, varscan2
- HOXA5 | c.312C>T p.S104= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1481016847, COSV56074067; called by muse, mutect2
- ICE1 | c.6717G>T p.R2239= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV56828458; called by muse, mutect2, varscan2
- IFT80 | c.22T>C p.L8= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV58449746; called by muse, mutect2, varscan2
- IGSF11 | c.1278G>T p.R426= (on ENST00000393775 / NM_001015887.3; = p.R425= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV61173257; called by muse, mutect2, varscan2
- ITM2A | c.138A>G p.K46= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV64811348; called by muse, mutect2, varscan2
- KIAA1210 | c.4032A>G p.P1344= | Silent (SNP) | VAF 164/211 reads (78%) | catalogued as rs767306887, COSV68178347; called by muse, mutect2, varscan2
- KRTAP13-2 | c.249C>A p.P83= | Silent (SNP) | VAF 26/34 reads (76%) | catalogued as COSV67762147, COSV67762369; called by muse, mutect2, varscan2
- LDB3 | c.714C>A p.A238= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs727503125, COSV53945426; called by muse, mutect2, varscan2
- LILRB1 | c.1257C>A p.P419= (on ENST00000427581; = p.P383= on NM_006669.6) | Silent (SNP) | VAF 37/123 reads (30%) | catalogued as COSV61119698; called by muse, mutect2, varscan2
- MAGEB6 | c.414T>A p.T138= | Silent (SNP) | VAF 39/48 reads (81%) | catalogued as COSV66872577, COSV66872688; called by muse, mutect2, varscan2
- MAGEL2 | c.2511C>T p.V837= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV58568010; called by muse, mutect2, varscan2
- MAP3K15 | c.3114C>A p.S1038= | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as COSV58833855; called by muse, mutect2, varscan2
- MAPT | c.678C>A p.S226= (on ENST00000262410 / NM_001377265.1; = p.S151= on NM_016835.4) | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99290235; called by muse, mutect2
- MEGF11 | c.1341G>T p.S447= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV56554792; called by muse, mutect2, varscan2
- MLNR | c.402C>A p.V134= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV54533266; called by muse, mutect2, varscan2
- MRC1 | c.1392G>C p.V464= | Silent (SNP) | VAF 75/143 reads (52%) | called by muse, mutect2, varscan2
- MYF6 | c.201C>A p.G67= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs762595246, COSV57352480; called by muse, mutect2, varscan2
- NAP1L4 | c.562C>T p.L188= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV65881553; called by muse, mutect2, varscan2
- NOP16 | c.96G>A p.P32= | Silent (SNP) | VAF 54/83 reads (65%) | catalogued as COSV51257798; called by muse, mutect2, varscan2
- NRSN1 | c.474C>T p.I158= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs779334465, COSV65894253; called by muse, mutect2, varscan2
- NTSR1 | c.120C>G p.G40= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV65139035, COSV65139842; called by muse, mutect2, varscan2
- ODC1 | c.774G>T p.A258= | Silent (SNP) | VAF 48/73 reads (66%) | catalogued as COSV52172824; called by muse, mutect2, varscan2
- OR2B6 | c.246A>T p.L82= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV55129303; called by muse, mutect2, varscan2
- OR2T3 | c.309G>T p.G103= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV62082867, COSV62083343; called by muse, mutect2, varscan2
- OR4K15 | c.561T>C p.T187= (on ENST00000305051; = p.T163= on NM_001005486.1) | Silent (SNP) | VAF 105/152 reads (69%) | catalogued as COSV59302137; called by muse, mutect2, varscan2
- OR52N2 | c.630G>T p.V210= | Silent (SNP) | VAF 76/142 reads (54%) | catalogued as COSV57677237; called by muse, mutect2, varscan2
- OR8U1 | c.567C>T p.C189= | Silent (SNP) | VAF 21/185 reads (11%) | catalogued as rs761519587, COSV100163858; called by muse, mutect2, varscan2
- OTX1 | c.573G>C p.V191= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV56995350; called by muse, mutect2, varscan2
- PAPPA2 | c.2904G>A p.L968= | Silent (SNP) | VAF 74/183 reads (40%) | catalogued as COSV62803557; called by muse, mutect2, varscan2
- PC | c.2640C>T p.S880= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs770582237, COSV58993243; called by muse, mutect2, varscan2
- PCDHB16 | c.1881C>A p.A627= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as COSV53366120; called by muse, mutect2, varscan2
- PLCD4 | c.2145T>A p.I715= | Silent (SNP) | VAF 34/170 reads (20%) | catalogued as COSV68744481; called by muse, mutect2, varscan2
- PLEKHA1 | c.522G>T p.R174= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV64569802; called by muse, mutect2, varscan2
- PLXNA2 | c.894C>T p.F298= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs555400028, COSV65442489; called by muse, mutect2, varscan2
- PREX2 | c.4506T>A p.A1502= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV55783785; called by muse, mutect2, varscan2
- REV3L | c.5271A>T p.S1757= | Silent (SNP) | VAF 8/127 reads (6%) | catalogued as COSV62620978; called by muse, mutect2
- RPS5 | c.606C>G p.S202= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV52191298; called by muse, mutect2, varscan2
- RYR3 | c.1290C>A p.A430= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV66799547; called by muse, mutect2, varscan2
- SEC16B | c.2301G>C p.L767= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV57627804; called by muse, mutect2, varscan2
- SHROOM3 | c.1980A>G p.S660= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs752464312, COSV56033898; called by muse, mutect2, varscan2
- SLC12A3 | c.2841G>A p.T947= (on ENST00000563236 / NM_001126108.2; = p.T956= on NM_000339.3) | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs754755570, COSV52634126; called by muse, mutect2, varscan2
- SLC43A1 | c.273C>G p.T91= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1462935889, COSV53559965; called by muse, mutect2, varscan2
- SPATA16 | c.378G>A p.K126= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs898717013, COSV63531075; called by muse, mutect2, varscan2
- SSTR3 | c.1236G>C p.T412= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs765709409, COSV60729826; called by muse, mutect2, varscan2
- TMEM26 | c.183C>T p.G61= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV67492960; called by muse, mutect2, varscan2
- TNR | c.2076C>A p.L692= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV54898575, COSV54904639; called by muse, mutect2, varscan2
- TPRG1L | c.585G>T p.P195= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV54562209, COSV54562379; called by muse, mutect2, varscan2
- TTLL3 | c.2070G>A p.R690= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV59615030; called by muse, mutect2, varscan2
- TTN | c.3705G>T p.V1235= (on ENST00000591111; = p.V1189= on NM_003319.4) | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV59904215; called by muse, mutect2, varscan2
- UNC5D | c.1263A>T p.T421= | Silent (SNP) | VAF 50/96 reads (52%) | catalogued as COSV54811303; called by muse, mutect2, varscan2
- VARS2 | c.2631C>A p.A877= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV58913363; called by muse, mutect2
- YLPM1 | c.6360C>T p.V2120= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs372259639; called by muse, mutect2, varscan2
- ZFAT | c.1707C>T p.S569= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV64741774; called by muse, mutect2, varscan2
- ZFPM2 | c.780G>T p.R260= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV65872777, COSV65874675; called by muse, mutect2, varscan2
- ZIC4 | c.714C>T p.F238= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV101267844, COSV67170598; called by muse, mutect2, varscan2
- ZNF676 | c.564A>T p.L188= (on ENST00000650058; = p.L156= on NM_001001411.3) | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as COSV68093862; called by muse, mutect2, varscan2
- AL161729.4 | chr9:95516634 G>T | 3'Flank (SNP) | VAF 12/21 reads (57%) | catalogued as COSV64602227; called by muse, mutect2, varscan2
- DLC1 | c.1348+90535C>A | Intron (SNP) | VAF 25/58 reads (43%) | catalogued as COSV99362396; called by muse, mutect2, varscan2
- DUSP22 | c.-1C>A | 5'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- HERC2P3 | n.558A>G | RNA (SNP) | VAF 24/135 reads (18%) | catalogued as rs377668971; called by muse, mutect2, varscan2
- HERC2P3 | n.156A>T | RNA (SNP) | VAF 26/166 reads (16%) | called by muse, mutect2, varscan2
- PRND | chr20:4732633 A>T | 3'Flank (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62852987 T>G | 5'Flank (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- SNORD114-6 | n.25C>T | RNA (SNP) | VAF 4/28 reads (14%) | catalogued as rs763872471; called by mutect2, varscan2
- SNORD116-8 | n.58G>A | RNA (SNP) | VAF 34/116 reads (29%) | catalogued as rs199601354; called by muse, mutect2, varscan2
- UROC1 | c.903-592T>C | Intron (SNP) | VAF 20/61 reads (33%) | catalogued as COSV52030686, COSV99331204; called by muse, mutect2, varscan2
- USP34 | chr2:61185507 G>C | 3'Flank (SNP) | VAF 20/283 reads (7%) | called by muse, mutect2
- ZBTB37 | chr1:173866308 T>C | 5'Flank (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2
